MMRF case MMRF_1761 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0467f89f-81ef-4888-bcd7-d3d00dc64591

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,392 days); ISS stage: III; Days to last known disease status: 1,065 days (2.9 years); Days to last follow up: 1,065 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 990 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 231 days; Days to treatment end: 260 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 231 days; Days to treatment end: 568 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 7.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1731 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.42 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 7.4 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 7.43 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 329 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.95 mmol/L; Albumin 36 g/L; Total Protein 8.1 g/dL; Glucose 3.8 mmol/L.
- Day 84 (ECOG 1): M Protein 5.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.4 µg/mL; Hemoglobin 6.01 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 5.01 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 7.54 mmol/L.
- Day 187: Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.95 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 8.91 mmol/L.
- Day 266 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.8 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 4 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 4.44 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 2.15 mmol/L.
- Day 386 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.9 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 3.41 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.8 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 7.4 g/dL; Glucose 3.85 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.61 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 3.45 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 0.73 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 139 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 4.73 mmol/L.
- Day 512: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.97 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 3.63 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 4.1 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 139 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 6.16 mmol/L.
- Day 596: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 3.17 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.88 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 743: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.9 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 7.32 mmol/L.
- Day 806 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.37 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 9.46 mmol/L.
- Day 897 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 47.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 3.79 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 11.2 mmol/L.
- Day 995: Serum Free Immunoglobulin Light Chain, Kappa 89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 4.79 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 14.7 mmol/L.
- Day 1,065: Serum Free Immunoglobulin Light Chain, Kappa 210 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 2.35 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.85 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 10.2 mmol/L.

Other clinical attributes
- Day 0: Weight: 104 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1761_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1761_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
